Gene-level copy-number profile of tumor specimen TCGA-13-1501-01A from TCGA case TCGA-13-1501, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 50.4 years (18,393 days).
Specimen TCGA-13-1501-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.886193e0-afe4-4d1b-9e48-7dd97ec354ce.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-1501-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/df1d3389-2b31-4b63-a88d-b99585471b2f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 16,760; copy number 2: 31,211; copy number 3: 9,044; copy number 4: 1,198; copy number 5: 1,116; copy number 6: 146; copy number 7: 324; copy number 11: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-1501-01A-01D-0472-01): tumor purity 0.65, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:37,005,646–37,029,069, 1 gene: FGD2.
- chr6:158,232,236–158,511,828, 1 gene (within-gene range 0–1): TULP4.
- chr6:158,282,841–158,428,379, 1 gene (within-gene range 0–1): AL360169.2.
- chr6:158,397,885–158,438,088, 2 genes: AL360169.1, RN7SL173P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,596 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:154,928,460–156,186,223, 33 genes, copy number 5: PAXIP1-AS2, PAXIP1, AC093726.1, AC093726.2, PAXIP1-AS1, HTR5A-AS1, HTR5A, AC093726.3, AC092628.2, AC092628.1, RN7SKP280, AC099552.1, AC099552.3, AC099552.5, AC099552.4, AC099552.2, AC144652.1, INSIG1, BLACE, AC008060.1, AC008060.4, AC008060.5, AC008060.3, EN2, CNPY1, AC009403.2, AC008060.2, AC009403.3, AC009403.1, RBM33, SHH, AC021218.1, Y_RNA.
- chr8:97,241,742–145,066,685, 763 genes, copy number 5–11 (broad region; genes not listed).
- chr11:68,008,578–104,682,581, 750 genes, copy number 5–7 (broad region; genes not listed).
- chr20:61,953,469–62,873,076, 50 genes, copy number 5: TAF4, MIR1257, AL137077.1, MIR3195, AL137077.2, LSM14B, PSMA7, SS18L1, MTG2, HRH3, OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3, BX640514.1, BX640514.2, AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1, LINC00686, NTSR1, AL357033.2, LINC00659, MRGBP, OGFR-AS1, OGFR, COL9A3, TCFL5, DPH3P1, ARF4P2.

Autosomal genes at a single copy (total copy number 1): 16,637. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
